Gene-level copy-number profile of tumor specimen ALCH-B0B4-TTP1-A from ALCHEMIST case ALCH-B0B4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.7 years (21,807 days).
Specimen ALCH-B0B4-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5636d890-8e2d-4c6b-acef-ca3560b49fee.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0B4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/f1a57394-7d79-45d2-9ee4-9e23fdac9630

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 698; copy number 1: 19,083; copy number 2: 30,150; copy number 3: 6,733; copy number 4: 1,751; copy number 5: 321; copy number 6: 82; copy number 7: 14; copy number 8: 12; copy number 9: 5; copy number 13: 3; copy number 22: 54.

Homozygous deletions (total copy number 0; autosomes only): 194 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:18,871,430–18,956,676, 4 genes: ALDH4A1, MIR4695, MIR1290, IFFO2.
- chr3:126,342,635–126,357,408, 1 gene: KLF15.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:45,890,216–45,895,970, 1 gene: AC122694.1.
- chr5:176,547,433–176,547,726, 1 gene (within-gene range 0–1): RN7SL684P.
- chr7:128,830,406–128,914,063, 6 genes: FLNC, FLNC-AS1, KCP, ATP6V1F, ATP6V1FNB, AC025594.1.
- chr8:43,539,137–46,028,892, 6 genes: AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1, AC118650.1.
- chr9:19,460,926–26,118,408, 94 genes (broad region; genes not listed).
- chr9:29,254,075–32,334,354, 21 genes: AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23, RNA5SP281, SLC25A5P8.
- chr9:40,883,634–40,883,763, 1 gene: AL353626.2.
- chr9:64,439,346–64,498,745, 6 genes: SNX18P9, CR769776.2, CYP4F25P, CNN2P3, GXYLT1P6, AL773524.1.
- chr9:137,867,925–138,253,217, 8 genes (within-gene range 0–1): AL772363.1, CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1, FAM157B.
- chr10:43,077,064–43,130,351, 1 gene: RET.
- chr10:86,668,507–86,736,072, 1 gene: LDB3.
- chr11:72,576,141–72,674,591, 5 genes (within-gene range 0–1): PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1.
- chr11:72,685,075–72,693,808, 1 gene (within-gene range 0–2): ARAP1-AS1.
- chr11:72,700,474–72,708,565, 2 genes (within-gene range 0–2): ARAP1-AS2, RPS12P20.
- chr11:119,185,457–119,196,769, 2 genes: PDZD3, CCDC153.
- chr12:34,149,839–37,576,384, 8 genes: AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1, ZNF970P.
- chr13:113,667,219–114,132,623, 13 genes: GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, RASA3, RASA3-IT1.
- chr17:2,712,309–2,712,833, 1 gene (within-gene range 0–2): AC005696.1.
- chr17:21,376,357–21,419,870, 1 gene: KCNJ12.
- chr18:37,234,119–37,236,242, 1 gene: AC015961.1.
- chr18:37,243,776–37,276,572, 2 genes (within-gene range 0–2): AC015961.2, AC090386.1.
- chr19:17,323,223–17,334,855, 1 gene (within-gene range 0–1): ANO8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 491 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,879,171–32,896,490, 2 genes, copy number 5: PPP1R2P1, HLA-Z.
- chr7:12,211,270–27,152,581, 206 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr7:32,456,963–33,877,180, 28 genes, copy number 5 (within-gene range 4–5): AC018641.1, SLC25A5P5, LSM5, AVL9, DPY19L1P1, ZNRF2P1, MIR550A2, MIR550B2, AC018645.3, LINC00997, AC018645.1, AC018645.2, DPY19L1P2, AC018648.1, KBTBD2, RP9P, AC083863.1, FKBP9, RNU6-388P, NT5C3A, RPS29P14, RN7SL505P, RP9, BBS9, AC074338.1, RNA5SP229, AC007312.1, AC006195.1.
- chr7:36,512,941–39,793,092, 66 genes, copy number 5 (broad region; genes not listed).
- chr7:52,891,837–55,713,252, 43 genes, copy number 5–6: SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P.
- chr7:148,438,309–149,424,890, 34 genes, copy number 22: RN7SL72P, AC083849.1, AC005229.2, AC005229.5, C7orf33, AC005229.1, AC005229.3, AC005229.4, CUL1, EZH2, RNU7-20P, Metazoa_SRP, RN7SL569P, RNY4, RNY3, RNY1, GHET1, PDIA4, RNU6-650P, COX6B1P1, ZNF786, ZNF425, RN7SL521P, ZNF398, AC004890.1, ZNF282, ZNF212, ZNF783, AC004890.3, AC004890.2, AC004941.2, NPM1P12, AC004941.1, AC073314.1.
- chr7:149,838,375–150,076,655, 12 genes, copy number 22: ZNF862, AC004877.2, AC004877.1, ATP6V0E2-AS1, ATP6V0E2, AC093458.1, AC093458.2, AC092681.3, AC092681.1, AC092681.2, AC092666.1, AC092666.2.
- chr7:152,590,641–152,855,378, 8 genes, copy number 22: AC104843.2, 5S_rRNA, AC104843.1, AC003109.1, XRCC2, ATP5PBP3, RN7SL845P, ACTR3B.
- chr8:101,034,868–104,256,094, 77 genes, copy number 6–13 (broad region; genes not listed).
- chr8:106,759,483–108,083,642, 9 genes, copy number 7–9: ABRA, AP003789.1, HMGB1P46, ANGPT1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4.
- chr14:92,794,305–92,839,947, 1 gene, copy number 6: GOLGA5.
- chr16:14,071,319–14,275,600, 5 genes, copy number 5: MRTFB, AC130650.2, AC130650.1, TVP23CP2, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 16,912. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
